Somatic mutation profile of tumor specimen TCGA-DA-A1I2-06A (aliquot TCGA-DA-A1I2-06A-21D-A19A-08) from TCGA case TCGA-DA-A1I2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.5 years (21,380 days).
Specimen TCGA-DA-A1I2-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3bdd5ea-8b2d-4141-aead-61953c62fd66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1I2-10A (Blood Derived Normal), aliquot TCGA-DA-A1I2-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e00031c-d981-4c9e-b192-428830a21457

The open-access MAF lists 150 somatic variants for this specimen: 89 protein-altering or splice-affecting, 54 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 54, Nonsense Mutation 4, Intron 3, RNA 3, 3'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACAN | c.6157G>A p.E2053K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs547217291, COSV61355453; called by muse, mutect2, varscan2
- ACCS | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55457061; called by muse, mutect2, varscan2
- ACMSD | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV51605418; called by muse, mutect2, varscan2
- ACVR1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs374836197; called by muse, mutect2, varscan2
- ANKRD6 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60228544; called by muse, mutect2, varscan2
- ATP8B4 | c.3452A>T p.K1151I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV52708701; called by muse, mutect2, varscan2
- BBS10 | c.2099C>T p.T700I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV67913033; called by muse, mutect2, varscan2
- BEND4 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); catalogued as COSV72468907; called by muse, mutect2, varscan2
- CARMIL2 | c.2495G>A p.W832* | Nonsense Mutation (SNP) | VAF 7/9 reads (78%) | catalogued as COSV58022814; called by muse, mutect2, varscan2
- CD163L1 | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58010568; called by muse, mutect2, varscan2
- CDH18 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs773695784, COSV56899995; called by muse, mutect2, varscan2
- COL4A6 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 103/116 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1453673529, COSV57858880; called by muse, mutect2, varscan2
- COL5A3 | c.2038G>A p.G680S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53405895; called by muse, mutect2, varscan2
- CPAMD8 | c.3928G>A p.G1310S (on ENST00000651564; = p.G1263S on NM_015692.5) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV71595740; called by muse, mutect2
- CUX2 | c.3337C>T p.P1113S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV55623873; called by muse, mutect2, varscan2
- DDB1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV57100809; called by muse, mutect2, varscan2
- DMXL1 | c.5161A>G p.I1721V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60704375; called by muse, varscan2
- DNAH17 | c.2768G>A p.G923D | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV67749388; called by muse, mutect2, varscan2
- DSCAM | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762198672, COSV68625338, COSV68626878; called by muse, mutect2, varscan2
- DSG3 | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57124029; called by muse, mutect2, varscan2
- EFCAB11 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57444723; called by muse, mutect2, varscan2
- EPHA6 | c.2303G>A p.R768K (on ENST00000389672 / NM_001080448.3; = p.R160K on NM_173655.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV67558194, COSV67586186; called by mutect2, varscan2
- FBN2 | c.2330A>G p.D777G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV52491631; called by muse, mutect2, varscan2
- FIG4 | c.1703A>G p.K568R | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.014); catalogued as rs1064797016, COSV57784793; ClinVar: uncertain significance; called by muse, mutect2
- FOLH1 | c.1848G>A p.M616I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57045256; called by muse, mutect2, varscan2
- GBP6 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as COSV100969627, COSV65010602; called by muse, mutect2, varscan2
- GIMAP8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.596); catalogued as COSV56229616; called by muse, mutect2, varscan2
- GOLGB1 | c.2087T>A p.L696H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61461517; called by muse, mutect2, varscan2
- GPR39 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61420927; called by muse, mutect2
- GPRC5C | c.1033G>A p.V345I (on ENST00000652232; = p.V300I on NM_018653.4) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61235234; called by muse, mutect2, varscan2
- GPRC6A | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as rs200889200, COSV59954739; called by muse, mutect2, varscan2
- GRIK1 | c.2536C>A p.L846M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV58710075; called by muse, mutect2, varscan2
- GRIK2 | c.2185C>T p.L729F | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59710910, COSV59765428; called by muse, mutect2, varscan2
- HLCS | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs547391411, COSV60791180; called by muse, mutect2, varscan2
- HTT | c.6170C>T p.S2057F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100751334; called by muse, mutect2, varscan2
- INPPL1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.286); catalogued as COSV53352907, COSV53353075; called by muse, mutect2, varscan2
- INSL4 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV53328609; called by muse, mutect2, varscan2
- JAKMIP2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV54597156; called by muse, mutect2, varscan2
- KCNT2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54063204; called by muse, mutect2, varscan2
- KRT20 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758318989, COSV51423879; called by muse, mutect2, varscan2
- LIG1 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs760367725, COSV54389355; called by muse, mutect2, varscan2
- LIMCH1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as rs767564154; called by muse, varscan2
- LNX2 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV60334167; called by muse, mutect2, varscan2
- MGAM | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as COSV72073550; called by muse, mutect2, varscan2
- MSH5 | c.812+1G>T p.X271_splice | Splice Site (SNP) | VAF 142/412 reads (34%) | catalogued as COSV65208602; called by muse, varscan2
- MYO3B | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV58693600; called by muse, mutect2
- NDST4 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs887477521, COSV52108382; called by muse, mutect2, varscan2
- NEK1 | c.3182G>A p.R1061K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV71454362; called by muse, mutect2, varscan2
- NEXMIF | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV50021645; called by muse, mutect2, varscan2
- NKAIN3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60648672; called by muse, mutect2, varscan2
- NPAP1 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61504120; called by muse, mutect2, varscan2
- NPSR1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.19); catalogued as rs754542933, COSV62196158; called by muse, mutect2, varscan2
- NWD1 | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 94/180 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV60337335, COSV60353201; called by muse, mutect2, varscan2
- OR10R2 | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63768417; called by muse, mutect2, varscan2
- OR4K5 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1489261314, COSV60002231; called by muse, mutect2, varscan2
- OR9K2 | c.764C>T p.S255F (on ENST00000305377; = p.S233F on NM_001005243.1) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59531322; called by muse, mutect2, varscan2
- PHLDB2 | c.2344G>C p.E782Q (on ENST00000393925 / NM_001134439.2; = p.E739Q on NM_145753.2) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV67307676; called by muse, mutect2, varscan2
- PLA1A | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56330288; called by muse, mutect2, varscan2
- PLPPR2 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV52258486; called by muse, mutect2, varscan2
- POLR2D | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV55758205; called by muse, mutect2, varscan2
- PSG6 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 137/246 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs778070572, COSV51829851; called by muse, mutect2, varscan2
- PTCD3 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54477938; called by muse, mutect2, varscan2
- PTPRB | c.480G>T p.R160S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.295); catalogued as COSV57692889; called by muse, mutect2, varscan2
- RAD17 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51456035; called by muse, mutect2, varscan2
- RPAP1 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV58537043; called by muse, mutect2, varscan2
- S100A7 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV64193052, COSV64193522; called by muse, mutect2, varscan2
- SH3TC1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV55280999; called by muse, mutect2, varscan2
- SHF | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV52049230; called by muse, mutect2, varscan2
- SIM1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53488750; called by muse, mutect2, varscan2
- SLC25A53 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 117/128 reads (91%) | catalogued as COSV62458273; called by muse, mutect2, varscan2
- SLC52A3 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs370499474, CM1211647; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST18 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1402603570, COSV52483697, COSV52513854; called by muse, mutect2, varscan2
- STOML3 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs962727518, COSV65509868; called by muse, mutect2, varscan2
- STX17 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52282150; called by muse, mutect2, varscan2
- TIMELESS | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs372449809; called by muse, mutect2, varscan2
- TMEM230 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs1181850088, COSV52531623; called by muse, mutect2, varscan2
- TRANK1 | c.5977G>A p.G1993R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57139763; called by muse, mutect2
- UBE3C | c.3211C>T p.L1071F | Missense Mutation (SNP) | VAF 87/155 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs770150348, COSV61950773; called by muse, mutect2, varscan2
- USF3 | c.6644A>G p.N2215S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57069546; called by muse, mutect2, varscan2
- USP40 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV52476855; called by muse, mutect2, varscan2
- ZNF823 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.965); catalogued as COSV100362501, COSV57872242; called by muse, varscan2
- ANKH | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DVL3 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- NT5C1B | c.481C>T p.P161S (on ENST00000359846 / NM_001199086.2; = p.P101S on NM_033253.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.211); called by muse, mutect2
- PWP1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PWP1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RAB2B | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TM9SF3 | c.1433_1434dup p.Y479Ifs*7 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS8 | c.2292G>A p.L764= | Silent (SNP) | VAF 45/77 reads (58%) | catalogued as COSV57291018; called by muse, mutect2, varscan2
- ADGRF5 | c.795C>T p.S265= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV51929606, COSV99346283; called by muse, varscan2
- ADGRG4 | c.9021A>C p.R3007= | Silent (SNP) | VAF 38/41 reads (93%) | catalogued as COSV54948845; called by muse, mutect2, varscan2
- AHNAK | c.8049T>A p.I2683= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV57203033; called by muse, mutect2
- ANK3 | c.9420A>G p.Q3140= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV55043233; called by muse, mutect2, varscan2
- ANKH | c.408C>T p.A136= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs761878319; called by muse, mutect2, varscan2
- BRF1 | c.1884G>A p.L628= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as rs1314604781, COSV59265762; called by muse, mutect2, varscan2
- CD300A | c.168C>T p.F56= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs1567979702, COSV60409448, COSV60410647; called by muse, mutect2, varscan2
- CDH10 | c.1701G>A p.V567= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV52569241; called by muse, mutect2, varscan2
- CHRDL2 | c.726C>T p.I242= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs754375233, COSV55221565; called by muse, mutect2, varscan2
- CHRNG | c.1086G>A p.L362= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV67315211; called by muse, mutect2, varscan2
- CPD | c.3738T>G p.G1246= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV56710556; called by muse, mutect2, varscan2
- CR1 | c.6057A>C p.G2019= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV65455644; called by muse, mutect2, varscan2
- CYP11B1 | c.1350C>T p.C450= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs756646001, COSV52824712; called by muse, mutect2, varscan2
- CYP46A1 | c.180C>T p.L60= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs1251549338, COSV55892962; called by muse, mutect2, varscan2
- DCLK3 | c.1639C>T p.L547= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV69362139; called by muse, mutect2, varscan2
- DMBT1 | c.7149C>T p.D2383= (on ENST00000338354 / NM_001377530.1; = p.D1626= on NM_004406.3) | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs749231034, COSV57533611; called by muse, mutect2, varscan2
- DNAH1 | c.9285C>T p.Y3095= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV70226150; called by muse, mutect2, varscan2
- DNAH7 | c.7155G>A p.R2385= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs150035002, COSV56751039; called by muse, mutect2, varscan2
- ELAPOR2 | c.1464C>T p.I488= (on ENST00000450689 / NM_001142749.3; = p.I321= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs867912367, COSV51883777; called by muse, mutect2, varscan2
- ELP1 | c.1863C>T p.V621= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV65896160; called by muse, mutect2, varscan2
- FARSA | c.432G>A p.R144= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as COSV58904023, COSV58905829; called by muse, mutect2, varscan2
- HTT | c.6171C>T p.S2057= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100751171; called by muse, mutect2, varscan2
- IARS2 | c.603T>C p.R201= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV56957379; called by muse, mutect2, varscan2
- LAMA2 | c.3210C>T p.F1070= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs1264195720, COSV70337774; called by muse, mutect2, varscan2
- LIMCH1 | c.1626C>T p.S542= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV100573221; called by muse, varscan2
- LRGUK | c.2340C>T p.T780= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2
- MAGI2 | c.3582C>T p.I1194= | Silent (SNP) | VAF 83/210 reads (40%) | catalogued as COSV62632721; called by muse, mutect2, varscan2
- MKI67 | c.2769G>A p.K923= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs1243909472, COSV64072430; called by muse, mutect2, varscan2
- MYH6 | c.3117C>T p.S1039= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs140314752; called by muse, mutect2, varscan2
- NLRP3 | c.975G>A p.R325= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV60219416, COSV60229185; called by muse, mutect2, varscan2
- NT5C1B | c.480C>T p.S160= (on ENST00000359846 / NM_001199086.2; = p.S100= on NM_033253.4) | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- NUTM1 | c.3051C>T p.L1017= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs7163178, COSV59215657; called by muse, mutect2, varscan2
- OR2B11 | c.198C>T p.F66= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV59509204; called by muse, mutect2, varscan2
- PARD3 | c.1662G>A p.R554= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV60744784; called by muse, mutect2, varscan2
- PKHD1L1 | c.144G>A p.R48= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV65736542; called by muse, mutect2, varscan2
- PLEC | c.4263C>T p.L1421= (on ENST00000322810 / NM_201380.4; = p.L1311= on NM_000445.5) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs782584875, COSV59601745; called by muse, mutect2, varscan2
- PLXNA4 | c.3390C>T p.I1130= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as COSV58103540; called by muse, varscan2
- POLR2D | c.264C>T p.L88= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- PRKG1 | c.1974C>A p.P658= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV64766163; called by mutect2, varscan2
- RAB2B | c.408C>T p.A136= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- RAD51D | c.957G>A p.Q319= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as rs147669627, COSV60003854; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCAF4 | c.1722C>T p.S574= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54584046; called by muse, mutect2, varscan2
- SHANK2 | c.5022G>A p.T1674= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs368202189; called by muse, mutect2, varscan2
- SHF | c.384A>C p.P128= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV52052078; called by muse, mutect2, varscan2
- SLC34A2 | c.1389C>T p.I463= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs1039506193, COSV65940540; called by muse, mutect2, varscan2
- SLCO6A1 | c.969C>T p.V323= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs866381547, COSV65805356; called by muse, mutect2, varscan2
- SYT10 | c.279C>T p.I93= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57337241; called by muse, mutect2
- TBX15 | c.444G>A p.V148= (on ENST00000369429 / NM_001330677.2; = p.V42= on NM_152380.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV52867138; called by muse, mutect2, varscan2
- TET1 | c.3846T>C p.Y1282= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs774797616, COSV65381806; called by muse, varscan2
- TGM6 | c.1747C>T p.L583= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV52477221, COSV99171677; called by muse, mutect2, varscan2
- TIMELESS | c.3081C>T p.I1027= | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.2346C>T p.I782= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV50536317; called by muse, mutect2, varscan2
- ZNF564 | c.447C>T p.A149= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV59434117; called by muse, mutect2, varscan2
- ADGRA1 | c.4-1223G>A | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV66928139; called by muse, mutect2
- C15orf54 | n.750G>A | RNA (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- C15orf54 | n.751G>A | RNA (SNP) | VAF 29/107 reads (27%) | catalogued as rs1318657658; called by muse, mutect2, varscan2
- CPLANE1 | c.*2840G>A | 3'UTR (SNP) | VAF 29/61 reads (48%) | catalogued as COSV57051226; called by muse, mutect2, varscan2
- HERC2P3 | n.2112G>A | RNA (SNP) | VAF 14/18 reads (78%) | called by mutect2, varscan2
- NEK7 | c.198+3217A>G | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2
- ZC3H14 | c.1280-1933C>T | Intron (SNP) | VAF 37/80 reads (46%) | catalogued as rs1487907728; called by muse, mutect2, varscan2
